Somatic mutation profile of tumor specimen TCGA-D8-A1JE-01A (aliquot TCGA-D8-A1JE-01A-11D-A13L-09) from TCGA case TCGA-D8-A1JE, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 62.1 years (22,683 days).
Specimen TCGA-D8-A1JE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12596e79-58c1-45cf-aa46-f9b349c46d4f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A1JE-10A (Blood Derived Normal), aliquot TCGA-D8-A1JE-10A-01D-A188-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a98746d-e2c1-4912-b2ed-aecc9099cf36

The open-access MAF lists 33 somatic variants for this specimen: 27 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 5, Nonsense Mutation 2, Frame Shift Del 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 28/64 reads (44%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACVR2B | c.718A>T p.K240* | Nonsense Mutation (SNP) | VAF 7/27 reads (26%) | catalogued as COSV61702701; called by muse, mutect2, varscan2
- ADGRV1 | c.5101C>T p.H1701Y | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.874); catalogued as COSV67988580; called by muse, mutect2, varscan2
- ANK3 | c.6691A>G p.N2231D | Missense Mutation (SNP) | VAF 53/329 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.014); catalogued as COSV55065098; called by muse, mutect2, varscan2
- ANK3 | c.5425T>A p.S1809T | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.036); catalogued as COSV55065108; called by muse, mutect2, varscan2
- ANKS4B | c.257A>T p.N86I | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as COSV61139456; called by muse, mutect2, varscan2
- CDK11A | c.1244C>T p.P415L (on ENST00000378633 / NM_001313896.2; = p.P412L on NM_024011.4) | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1051015506, COSV62265913; called by muse, mutect2, varscan2
- CTSV | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 51/272 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV52345123; called by muse, varscan2
- CYTH4 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.081); catalogued as COSV50633479; called by muse, mutect2
- DDX55 | c.577C>G p.P193A | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53016555; called by muse, mutect2, varscan2
- DHX9 | c.2588G>A p.R863H | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as rs982568068, COSV62360359; called by muse, mutect2, varscan2
- DNMT3A | c.2669G>A p.G890D | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs752160822, COSV53061136, COSV53081116; called by muse, mutect2, varscan2
- FCSK | c.166A>C p.S56R | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as COSV55372379; called by muse, mutect2, varscan2
- GPATCH2 | c.701A>G p.E234G | Missense Mutation (SNP) | VAF 160/307 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as COSV65128021; called by muse, mutect2, varscan2
- IGFBP2 | c.563T>C p.L188P | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.733); catalogued as COSV52080629; called by muse, varscan2
- IL9R | c.1356G>A p.W452* | Nonsense Mutation (SNP) | VAF 11/25 reads (44%) | catalogued as rs1412958447; called by muse, mutect2, varscan2
- KIF13B | c.3275G>A p.R1092H | Missense Mutation (SNP) | VAF 42/212 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759564273, COSV72954492; called by muse, mutect2, varscan2
- KIF14 | c.1349G>T p.G450V | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66262398; called by muse, mutect2, varscan2
- MKI67 | c.6884A>G p.N2295S | Missense Mutation (SNP) | VAF 96/403 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.428); catalogued as COSV100896978, COSV64075230; called by muse, mutect2, varscan2
- MROH9 | c.481A>G p.I161V | Missense Mutation (SNP) | VAF 34/195 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV63012135; called by muse, mutect2, varscan2
- MSI1 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV57456759; called by muse, mutect2, varscan2
- MYO3A | c.2794-1G>A p.X932_splice | Splice Site (SNP) | VAF 29/119 reads (24%) | catalogued as rs200531358, COSV56336586; called by muse, mutect2, varscan2
- NLRP8 | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.031); catalogued as rs532289570, COSV52587105; called by muse, mutect2, varscan2
- PSIP1 | c.246G>T p.W82C | Missense Mutation (SNP) | VAF 47/341 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV66254984; called by muse, mutect2, varscan2
- RB1CC1 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 10/185 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as COSV99209045; called by muse, mutect2
- ZNF451 | c.1215C>A p.S405R | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.06); catalogued as COSV62598234; called by muse, mutect2, varscan2
- FAT4 | c.5278_5279del p.M1760Afs*8 | Frame Shift Del (DEL) | VAF 12/61 reads (20%) | called by mutect2, pindel, varscan2
- BPIFA2 | c.33C>T p.C11= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as rs771075584, COSV53610353; called by muse, mutect2, varscan2
- CIDEC | c.480C>T p.N160= | Silent (SNP) | VAF 20/110 reads (18%) | catalogued as rs144384365, COSV61061133; called by muse, mutect2, varscan2
- L3MBTL1 | c.579G>A p.A193= (on ENST00000418998 / NM_001377303.1; = p.A103= on NM_015478.7) | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs761030705, COSV64232922; called by muse, mutect2, varscan2
- MARF1 | c.4113A>T p.T1371= | Silent (SNP) | VAF 12/93 reads (13%) | catalogued as COSV60025293; called by muse, mutect2, varscan2
- PCDHA1 | c.1854G>A p.A618= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as rs543937372, COSV65374214; called by muse, varscan2
- NRG1 | c.1269-473G>T | Intron (SNP) | VAF 21/113 reads (19%) | catalogued as rs781780058, COSV55160141, COSV55164651; called by muse, mutect2, varscan2
